MMRF case MMRF_1624 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/751d6828-9826-49ce-884e-7194755bfadb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.8 years (25,857 days); ISS stage: II; Days to last known disease status: 1,239 days (3.4 years); Days to last follow up: 1,239 days (3.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 142 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 184 days; Days to treatment end: 184 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 292 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8: M Protein 4.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 85.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.5 mg/dL; Immunoglobulin G 59.1 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.9 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 10.2 g/dL; Glucose 6.49 mmol/L.
- Day 62 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 7.22 g/L; Immunoglobulin A 0.323 g/L; Immunoglobulin M 0.213 g/L; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 6.99 mmol/L.
- Day 142 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.63 mg/dL; Immunoglobulin G 4.64 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.221 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 4.62 mmol/L.
- Day 279 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 9.33 g/L; Immunoglobulin A 0.528 g/L; Immunoglobulin M 0.238 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 5.56 mmol/L.
- Day 329 (ECOG 0): Hemoglobin 7.87 mmol/L; Leukocytes 4.65 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 6.6 g/dL; Glucose 6.33 mmol/L.
- Day 427: Hemoglobin 7.69 mmol/L; Leukocytes 4.43 ×10⁹/L; Absolute Neutrophil 1.77 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.05 mmol/L; Albumin 34 g/L; Total Protein 7 g/dL; Glucose 6.44 mmol/L.
- Day 518 (ECOG 1): Hemoglobin 7.38 mmol/L; Leukocytes 4.43 ×10⁹/L; Absolute Neutrophil 1.59 ×10⁹/L; Platelets 214 ×10⁹/L.
- Day 574: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.89 mg/dL; Immunoglobulin G 9.93 g/L; Immunoglobulin A 1.36 g/L; Immunoglobulin M 0.311 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.43 ×10⁹/L; Absolute Neutrophil 2.09 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2 mmol/L; Albumin 32 g/L; Total Protein 6.6 g/dL; Glucose 7.04 mmol/L.
- Day 721 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.3 mg/dL; Immunoglobulin G 9.75 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.03 mmol/L; Albumin 32 g/L; Total Protein 6.4 g/dL; Glucose 5.28 mmol/L.
- Day 784 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.2 mg/dL; Immunoglobulin G 10.8 g/L; Beta 2 Microglobulin 1.9 µg/mL; Hemoglobin 8 mmol/L; Leukocytes 3.78 ×10⁹/L; Absolute Neutrophil 1.35 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.08 mmol/L; Albumin 33 g/L; Total Protein 7 g/dL; Glucose 8.03 mmol/L.
- Day 873 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.5 mg/dL; Immunoglobulin G 12.9 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.37 ×10⁹/L; Absolute Neutrophil 1.43 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.05 mmol/L; Albumin 34 g/L; Total Protein 6.9 g/dL; Glucose 5.12 mmol/L.
- Day 938 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.75 mg/dL; Immunoglobulin G 12.4 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.76 ×10⁹/L; Absolute Neutrophil 1.67 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 7.1 g/dL; Glucose 5.5 mmol/L.
- Day 1,029 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.75 mg/dL; Immunoglobulin G 10.9 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.35 ×10⁹/L; Absolute Neutrophil 1.41 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.03 mmol/L; Albumin 31 g/L; Total Protein 6.3 g/dL; Glucose 6.49 mmol/L.
- Day 1,127 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.5 mg/dL; Immunoglobulin G 12.5 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.05 ×10⁹/L; Absolute Neutrophil 0.88 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.08 mmol/L; Albumin 32 g/L; Total Protein 6.8 g/dL; Glucose 7.54 mmol/L.
- Day 1,239 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.92 mg/dL; Immunoglobulin G 14.7 g/L; Beta 2 Microglobulin 1.96 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 3.78 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.03 mmol/L; Albumin 33 g/L; Total Protein 7 g/dL; Glucose 4.95 mmol/L.

Other clinical attributes
- Day -8: Weight: 98 kg; Height: 181 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1624_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_1624_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
